Somatic mutation profile of tumor specimen C3L-06649-01 (aliquot CPT0358920006) from CPTAC case C3L-06649, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 64.1 years (23,395 days).
Specimen C3L-06649-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2efa68f1-2512-42e7-affd-a0d0fad6f4a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06649-31 (Blood Derived Normal), aliquot CPT0359010005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d78b6a6c-06d9-4574-b6c6-17f185ffee85

The open-access MAF lists 65 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Nonsense Mutation 7, Frame Shift Del 3, Intron 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.774A>T p.E258D | Missense Mutation (SNP) | VAF 31/237 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV52752502, COSV52980614; called by muse, mutect2, varscan2
- ALDH1B1 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 35/512 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs770591719, COSV66619291; called by muse, mutect2
- APBB1IP | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 37/374 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); catalogued as rs1227672195; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs765705848, COSV63437562; called by muse, varscan2
- ATP1B3 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53950565; called by muse, mutect2
- BAZ1A | c.4114C>A p.P1372T | Missense Mutation (SNP) | VAF 47/436 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62412139; called by muse, mutect2, varscan2
- DCC | c.1382C>A p.T461N | Missense Mutation (SNP) | VAF 25/409 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV59119419; called by muse, mutect2
- FBN3 | c.1633G>A p.V545M | Missense Mutation (SNP) | VAF 36/361 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs142269916; called by muse, mutect2
- FNBP4 | c.1536A>G p.I512M | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as rs771274911; called by muse, mutect2, varscan2
- FRY | c.1201C>T p.R401* | Nonsense Mutation (SNP) | VAF 17/312 reads (5%) | catalogued as rs1399764760, COSV66567390; called by muse, mutect2
- GALNT9 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 56/377 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1482524776, COSV100202158; called by muse, mutect2, varscan2
- GPR162 | c.1015G>A p.E339K (on ENST00000311268 / NM_019858.2; = p.E55K on NM_014449.2) | Missense Mutation (SNP) | VAF 46/422 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs1555119900; called by muse, mutect2, varscan2
- IGSF10 | c.5779C>T p.R1927* | Nonsense Mutation (SNP) | VAF 32/426 reads (8%) | catalogued as rs370097307; called by muse, mutect2
- MAGEC3 | c.1400T>G p.L467R | Missense Mutation (SNP) | VAF 135/369 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53581041, COSV68924122; called by muse, mutect2, varscan2
- MAP2 | c.3215T>G p.L1072R | Missense Mutation (SNP) | VAF 41/485 reads (8%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.305); catalogued as rs576483648, COSV52291878; called by muse, mutect2
- OBSL1 | c.5381C>T p.P1794L | Missense Mutation (SNP) | VAF 46/461 reads (10%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.907); catalogued as rs1268074829; called by muse, mutect2, varscan2
- OLFML3 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 33/449 reads (7%) | catalogued as rs1309175315; called by muse, mutect2
- OPRPN | c.194T>C p.F65S | Missense Mutation (SNP) | VAF 42/504 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs752382705; called by muse, mutect2
- PDE6C | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 42/487 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747162323, COSV65117276; called by muse, mutect2
- PHTF1 | c.2193C>G p.I731M | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1262516216; called by muse, mutect2, varscan2
- PREX1 | c.4579G>A p.V1527I | Missense Mutation (SNP) | VAF 70/345 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs772739610, COSV64251510; called by muse, mutect2, varscan2
- PTPRB | c.3766del p.E1256Rfs*96 | Frame Shift Del (DEL) | VAF 24/253 reads (9%) | catalogued as COSV54245889; called by mutect2, pindel, varscan2
- SBK3 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 38/498 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs991976294; called by muse, mutect2
- SLC9A2 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1444790071; called by muse, mutect2, varscan2
- ST3GAL3 | c.886G>A p.A296T (on ENST00000361392 / NM_174964.4; = p.A281T on NM_006279.5) | Missense Mutation (SNP) | VAF 41/487 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs371540962; called by muse, mutect2
- ZNF541 | c.1152G>T p.W384C | Missense Mutation (SNP) | VAF 68/532 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as rs1397612244; called by muse, mutect2, varscan2
- ABCG2 | c.689G>C p.R230T | Missense Mutation (SNP) | VAF 38/317 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ADAMTS14 | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 58/530 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- ASB15 | c.1227T>A p.Y409* | Nonsense Mutation (SNP) | VAF 22/342 reads (6%) | called by muse, mutect2
- C2orf16 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 47/431 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- C2orf16 | c.179A>T p.K60I | Missense Mutation (SNP) | VAF 46/436 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- CH25H | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CHD2 | c.2956G>T p.E986* | Nonsense Mutation (SNP) | VAF 32/324 reads (10%) | called by muse, mutect2, varscan2
- DOCK2 | c.1789C>T p.R597W | Missense Mutation (SNP) | VAF 54/429 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EIF3B | c.1735G>C p.V579L | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- ENTPD8 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 90/507 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERBB3 | c.3985T>A p.W1329R | Missense Mutation (SNP) | VAF 37/374 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EXOSC2 | c.734T>C p.V245A | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FANCB | c.1436G>A p.W479* | Nonsense Mutation (SNP) | VAF 26/173 reads (15%) | called by muse, mutect2, varscan2
- FFAR4 | c.1027A>T p.R343W | Missense Mutation (SNP) | VAF 47/415 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- HCN1 | c.1103G>T p.S368I | Missense Mutation (SNP) | VAF 49/449 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- MYH9 | c.3861del p.L1288Ffs*38 | Frame Shift Del (DEL) | VAF 36/322 reads (11%) | called by mutect2, pindel, varscan2
- PGLYRP4 | c.555T>G p.S185R | Missense Mutation (SNP) | VAF 52/430 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- PIKFYVE | c.1676T>G p.I559R | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PLAAT2 | c.387+1G>T p.X129_splice | Splice Site (SNP) | VAF 17/226 reads (8%) | called by muse, mutect2
- RIPOR3 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 46/497 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2
- SLC49A3 | c.97del p.L33Cfs*73 | Frame Shift Del (DEL) | VAF 47/434 reads (11%) | called by mutect2, pindel, varscan2
- ZNF804A | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 34/398 reads (9%) | called by muse, mutect2
- A2M | c.1459C>T p.L487= | Silent (SNP) | VAF 34/329 reads (10%) | called by muse, mutect2, varscan2
- ABCB5 | c.1626C>T p.N542= (on ENST00000404938 / NM_001163941.2; = p.N97= on NM_178559.6) | Silent (SNP) | VAF 49/494 reads (10%) | called by muse, mutect2, varscan2
- ACO1 | c.1299C>A p.A433= | Silent (SNP) | VAF 42/379 reads (11%) | called by muse, mutect2, varscan2
- COL4A6 | c.2364C>T p.H788= | Silent (SNP) | VAF 60/193 reads (31%) | catalogued as rs375971196, COSV57881919; called by muse, varscan2
- CRB1 | c.2251T>C p.L751= | Silent (SNP) | VAF 30/446 reads (7%) | called by muse, mutect2
- GLI2 | c.4338C>T p.L1446= (on ENST00000361492 / NM_001374353.1; = p.L1463= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/566 reads (10%) | catalogued as rs759318749; called by muse, mutect2
- HCN1 | c.1104C>T p.S368= | Silent (SNP) | VAF 48/451 reads (11%) | called by muse, mutect2, varscan2
- HMGXB3 | c.1404A>G p.E468= (on ENST00000613459; = p.E222= on NM_014983.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/484 reads (10%) | called by muse, mutect2
- NDUFS2 | c.450C>G p.A150= | Silent (SNP) | VAF 49/451 reads (11%) | called by muse, mutect2
- PCDHGA4 | c.636C>T p.D212= | Silent (SNP) | VAF 46/462 reads (10%) | catalogued as rs750434737, COSV53977600; called by muse, mutect2
- PIK3CD | c.252C>T p.D84= | Silent (SNP) | VAF 33/445 reads (7%) | catalogued as rs755377648, COSV63131829; called by muse, mutect2
- PNPLA7 | c.483C>T p.I161= | Silent (SNP) | VAF 83/495 reads (17%) | catalogued as rs143980960; called by muse, mutect2, varscan2
- TRBV28 | c.312G>A p.Q104= | Silent (SNP) | VAF 28/312 reads (9%) | called by muse, mutect2
- UBN1 | c.2124C>T p.G708= | Silent (SNP) | VAF 74/419 reads (18%) | called by muse, mutect2, varscan2
- TJP2 | c.*134C>T | 3'UTR (SNP) | VAF 43/374 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.34265-2981A>G | Intron (SNP) | VAF 18/192 reads (9%) | called by muse, mutect2
- TTN | c.10361-3964dup | Intron (INS) | VAF 51/391 reads (13%) | catalogued as rs1560961746; called by mutect2, varscan2
